Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAW1, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAW1-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver NOS
C22.0

QW 4/22/14

DIAGNOSIS:

Liver, right, hemihepatectomy:

1. Hepatocellular carcinoma, S8
- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 6.8x5.8x4.5cm
- 3) Gross type: multinodular confluent type
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular and pseudoglandular type
- 6) Cell type: classic and oncocytic type
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 4/4
The major differentiation: 2/4
- 8) Fatty change: absent
- 9) Hemorrhage/peliosis: present (20%)
- 10) Tumor necrosis: present (5%)
- 11) Vascular invasion(microscopic): present
- 12) Capsule formation: partial
- 13) Infiltration of capsule: present
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: clear (safety margin: 1.4cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: present
- 22) Pathologic stage: AJCC (pT3), (pT3)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Cirrhosis: present, active
- b) Dysplasia: absent
2. Hepatocellular carcinoma, S7
- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 1.5x1.4x1.3cm
- 3) Gross type: expanding nodular type
- 4) Satellite nodule: absent
- 5) Histologic type: solid pattern
- 6) Cell type: classic type
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 3/4
The major differentiation: 2/4
- 8) Fatty change: present (50%)
- 9) Hemorrhage/peliosis: present (2%)
- 10) Tumor necrosis: absent

[page 2 of 2]
Pathology report

- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: absent
- 13) Infiltration of capsule: absent
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Scrosal invasion: present
- 19) Surgical margin: clear (safety margin: 6.5cm)

Source: NCI Genomic Data Commons file 524ad38e-4d54-472d-a82a-995f77887e29 (TCGA-DD-AAW1.3ED5891B-FD39-4F88-94AA-D040867A51B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).